Somatic mutation profile of tumor specimen TCGA-4V-A9QJ-01A (aliquot TCGA-4V-A9QJ-01A-11D-A423-09) from TCGA case TCGA-4V-A9QJ, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B3, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 64.4 years (23,510 days).
Specimen TCGA-4V-A9QJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46e8e514-2738-4144-be9a-2297c836c4d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4V-A9QJ-11A (Solid Tissue Normal), aliquot TCGA-4V-A9QJ-11A-11D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9c84002-1c7f-4b33-8041-dda2e2465f14

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 11, Silent 7.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 7/68 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AP1M1 | c.883A>C p.I295L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as rs1196680088, COSV52225260; called by muse, mutect2
- C12orf50 | c.739A>G p.T247A | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1054253226; called by muse, mutect2
- PCDHA12 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs1187719075; called by muse, mutect2
- CSF3R | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- EXT1 | c.1940A>G p.D647G | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- GAS2 | c.545C>G p.P182R | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- IGSF1 | c.1667C>G p.T556R | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.986); called by muse, mutect2
- NR1H2 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.166); called by muse, mutect2
- SNX14 | c.1357G>C p.V453L (on ENST00000314673 / NM_001350535.1; = p.V409L on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.954); called by muse, mutect2
- UHRF2 | c.2094T>G p.H698Q | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID3C | c.1200C>T p.P400= | Silent (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
- BAZ1A | c.1461A>G p.E487= | Silent (SNP) | VAF 5/100 reads (5%) | called by muse, mutect2
- DNAH9 | c.9594C>A p.P3198= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- KIF3B | c.2031T>C p.G677= | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- NCBP2L | c.375C>T p.R125= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs773993102, COSV64943883; called by muse, mutect2, varscan2
- TRANK1 | c.7092G>A p.R2364= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- TTN | c.8730C>A p.V2910= (on ENST00000591111; = p.V2864= on NM_003319.4) | Silent (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
